Somatic mutation profile of tumor specimen TCGA-XF-A9SL-01A (aliquot TCGA-XF-A9SL-01A-11D-A391-08) from TCGA case TCGA-XF-A9SL, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.7 years (25,460 days).
Specimen TCGA-XF-A9SL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16774ae5-a30e-4b88-85eb-d593b29b2fc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SL-10A (Blood Derived Normal), aliquot TCGA-XF-A9SL-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8657378-eca3-4b53-b64b-953a0ecb8d16

The open-access MAF lists 74 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 13, Nonsense Mutation 5, Splice Region 1, RNA 1, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD6 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV55910331; called by mutect2, varscan2
- ABR | c.955C>T p.R319W (on ENST00000302538 / NM_021962.5; = p.R282W on NM_001092.5) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261297224, COSV52142343; called by muse, mutect2
- AHR | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54122461, COSV54126102; called by muse, mutect2
- ALX1 | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.167); catalogued as rs1565944478, COSV57494063; called by muse, mutect2
- ANKRD12 | c.3713C>G p.S1238* | Nonsense Mutation (SNP) | VAF 4/87 reads (5%) | catalogued as COSV100042052; called by muse, mutect2
- ANKRD12 | c.4708C>G p.Q1570E | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV50846615; called by muse, mutect2
- CBLL1 | c.714C>G p.I238M | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.605); catalogued as COSV56030510; called by muse, mutect2
- CCDC173 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as COSV101352369; called by muse, mutect2
- COL2A1 | c.394G>T p.G132* | Nonsense Mutation (SNP) | VAF 7/195 reads (4%) | catalogued as COSV100477427; called by muse, mutect2
- CRK | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs1242359268, COSV56032556; called by muse, mutect2
- DAXX | c.957T>A p.D319E | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.153); catalogued as COSV56472482; called by muse, mutect2
- DDI2 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60781397, COSV99072119; called by muse, mutect2
- DLL3 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV52696661; called by muse, mutect2
- DNASE1L3 | c.144C>T p.V48= | Splice Region (SNP) | VAF 8/148 reads (5%) | catalogued as COSV59157347; called by muse, mutect2
- ESR1 | c.874T>C p.W292R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.253); catalogued as COSV52801979; called by muse, mutect2
- FLT1 | c.2188C>G p.H730D | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.124); catalogued as COSV56741220, COSV56742167; called by muse, mutect2
- FUT1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV59569970; called by muse, mutect2
- GPC6 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV65536461; called by muse, mutect2
- GRPEL2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV61388175; called by muse, mutect2
- IFNA4 | c.114G>C p.L38F | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as COSV101427084; called by muse, mutect2
- ITPR2 | c.1618G>C p.D540H | Missense Mutation (SNP) | VAF 11/341 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV67275754; called by muse, mutect2
- KIF14 | c.1037C>G p.S346C | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV66264016; called by muse, mutect2
- LGSN | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV101040722, COSV65727370; called by muse, mutect2
- MASTL | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100668965, COSV60912248; called by muse, mutect2
- MESP2 | c.1030A>G p.S344G | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV100510854; called by muse, mutect2
- MTA1 | c.2018C>A p.S673* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100231763; called by muse, mutect2, varscan2
- MUC4 | c.13759C>T p.Q4587* (on ENST00000463781 / NM_018406.7; = p.Q351* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs776981783, COSV100206371; called by muse, mutect2, varscan2
- MUC4 | c.1235T>A p.L412Q | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.774); catalogued as COSV62190474; called by muse, mutect2
- MUC5B | c.9551C>T p.S3184F | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs975498513, COSV71595252; called by muse, mutect2
- MYO16 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs776925771, COSV51803396; called by muse, mutect2, varscan2
- NCSTN | c.2083G>C p.D695H | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV54191559; called by muse, mutect2
- NELFCD | c.1682T>C p.L561P (on ENST00000602795; = p.L543P on NM_198976.4) | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99413726; called by muse, mutect2
- NOA1 | c.1919G>A p.R640K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV51736779, COSV51738668; called by muse, mutect2
- NOM1 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99316040; called by muse, mutect2
- OR2T4 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.637); catalogued as COSV63545107; called by muse, mutect2
- PDXDC1 | c.2173C>G p.H725D | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); catalogued as COSV55075870; called by muse, mutect2
- PNPLA4 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV101124425; called by muse, mutect2
- PPL | c.2894A>C p.Q965P | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV52172652; called by muse, mutect2
- RASA2 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 7/138 reads (5%) | catalogued as COSV99656704; called by muse, mutect2
- RP1L1 | c.3311C>T p.S1104F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV66759917, COSV66760483; called by muse, mutect2
- RTL9 | c.3631C>G p.L1211V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.072); catalogued as COSV71826335; called by mutect2, varscan2
- RUFY1 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60163645; called by muse, mutect2
- SPATA5 | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99916362; called by muse, mutect2
- SPRYD4 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.255); catalogued as COSV57666021; called by muse, mutect2
- TAF9B | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV59371564, COSV59372304; called by muse, mutect2, varscan2
- TGOLN2 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 48/741 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs1381788083, COSV56407571; called by muse, mutect2
- TMCC2 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58006404; called by muse, mutect2
- TMPRSS4 | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV71110378; called by muse, mutect2, varscan2
- TRAPPC8 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as COSV51977076; called by muse, mutect2
- TRIM24 | c.1877A>G p.D626G (on ENST00000343526 / NM_015905.3; = p.D592G on NM_003852.4) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV58977786; called by muse, mutect2
- TRIM47 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1015270154, COSV54668053; called by muse, mutect2, varscan2
- TRPA1 | c.2984T>C p.L995P | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51573414; called by muse, mutect2
- VAPA | c.611G>C p.R204T (on ENST00000400000 / NM_194434.3; = p.R249T on NM_003574.6) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100486179; called by muse, mutect2
- XIRP2 | c.2905G>A p.E969K (on ENST00000628543; = p.E1144K on NM_152381.6) | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs940872811, COSV54732281; called by muse, mutect2
- YAE1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as COSV56233692; called by muse, mutect2
- ZNF280C | c.2122C>G p.Q708E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV63969907; called by muse, mutect2, varscan2
- ZNF443 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV56894153; called by muse, mutect2
- ADGRG1 | c.441_442del p.N148Hfs*137 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- G6PD | c.1288-1_1288del p.X430_splice | Splice Site (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- ATP8A2 | c.3093C>T p.V1031= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV54975567; called by muse, mutect2, varscan2
- CSMD2 | c.5547G>T p.S1849= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV53958803; called by muse, mutect2, varscan2
- ENPP2 | c.1263T>C p.F421= (on ENST00000075322 / NM_001040092.3; = p.F473= on NM_006209.5) | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV99309321; called by muse, mutect2
- GCK | c.876C>G p.L292= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as rs1245789780, COSV60788048; called by muse, mutect2, varscan2
- GPC5 | c.1320G>A p.Q440= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV65627950; called by muse, mutect2, varscan2
- MAP2K6 | c.558C>T p.L186= | Silent (SNP) | VAF 11/226 reads (5%) | catalogued as COSV63007306; called by muse, mutect2
- NEK10 | c.747C>G p.L249= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1346092518, COSV58289184; called by muse, mutect2, varscan2
- PARP3 | c.720G>C p.L240= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV51756383; called by muse, mutect2
- PCDHA2 | c.1206G>A p.K402= | Silent (SNP) | VAF 7/189 reads (4%) | catalogued as COSV65365551; called by muse, mutect2
- RSPH6A | c.894G>A p.E298= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV55575242; called by muse, mutect2, varscan2
- SAFB2 | c.126G>A p.L42= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1026940861, COSV52653841; called by muse, mutect2
- SPEF2 | c.3558G>A p.K1186= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as COSV61553347; called by muse, mutect2
- SVIL | c.1642C>T p.L548= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as COSV63447921; called by muse, mutect2
- C22orf15 | c.326-22C>T | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as rs1185298357; called by muse, mutect2
- SNORD114-20 | n.51T>A | RNA (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
